Somatic mutation profile of tumor specimen MP2PRT-PATKJC-TMP1-A (aliquot MP2PRT-PATKJC-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATKJC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.7 years (3,553 days).
Specimen MP2PRT-PATKJC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27984164-17e0-4b41-ae84-41fc44b532f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATKJC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATKJC-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aab20495-1a81-41c5-bf02-aabffb7e132c

The open-access MAF lists 15 somatic variants for this specimen: 15 protein-altering or splice-affecting.
By variant classification: Missense Mutation 11, In Frame Ins 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKR1E2 | c.302T>C p.I101T | Missense Mutation (SNP) | VAF 83/305 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1186073286; called by muse, mutect2, varscan2
- C16orf72 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 58/824 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as rs749401995; called by muse, mutect2
- CACNA1H | c.2240G>A p.R747H | Missense Mutation (SNP) | VAF 62/551 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs781343756, COSV61993560; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COG7 | c.2186C>T p.P729L | Missense Mutation (SNP) | VAF 75/272 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.592); catalogued as rs1453341585; called by muse, mutect2, varscan2
- FAM71E2 | c.2498C>T p.S833L | Missense Mutation (SNP) | VAF 122/397 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.182); catalogued as rs901214391; called by muse, varscan2
- GNAO1 | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 36/252 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV52614358, COSV52621333; called by muse, varscan2
- LRWD1 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 69/483 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as rs888310940; called by muse, mutect2, varscan2
- MARVELD3 | c.862G>A p.V288I | Missense Mutation (SNP) | VAF 138/427 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773605578, COSV51705344; called by muse, mutect2, varscan2
- MYO3A | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 43/315 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs777926817, COSV99779776; called by muse, mutect2, varscan2
- PCDHGB6 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 38/573 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99531762; called by muse, mutect2
- ZFYVE16 | c.4069C>T p.R1357W | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs144415532; called by muse, mutect2, varscan2
- CREBBP | c.4315_4320delinsCCT p.F1439_F1440delinsP | In Frame Del (DEL) | VAF 58/342 reads (17%) | called by pindel, varscan2*
- E2F1 | c.445_446insCCG p.D148_G149insA | In Frame Ins (INS) | VAF 108/345 reads (31%) | called by mutect2, pindel, varscan2
- PLCB3 | c.3258_3259insGCCCCC p.M1086_N1087insAP | In Frame Ins (INS) | VAF 54/226 reads (24%) | called by mutect2, pindel*, varscan2
- PPP1R15A | c.489_490insCCC p.A163_E164insP | In Frame Ins (INS) | VAF 94/348 reads (27%) | called by mutect2, pindel, varscan2
